Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GJ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GJ-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: diameter 5 cm

Lymph node status: 19 negative lymph nodes

Any comments or amendments: radical resection

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal, third
C15.5
Q11/28/14

Source: NCI Genomic Data Commons file 44785633-b7d6-4ba3-b251-29471f1b1769 (TCGA-2H-A9GJ.AE005FFA-3FCC-4E8C-AF11-398E0FB2B8A7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).